Somatic mutation profile of tumor specimen TCGA-44-2661-01A (aliquot TCGA-44-2661-01A-01D-1105-08) from TCGA case TCGA-44-2661, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.3 years (25,313 days).
Specimen TCGA-44-2661-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4aa62ab-85aa-4ff9-816f-de4091d87daf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2661-10A (Blood Derived Normal), aliquot TCGA-44-2661-10A-01D-1105-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/663bd60e-4763-41ef-8834-bb1e18aa37f3

The open-access MAF lists 46 somatic variants for this specimen: 28 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 16, RNA 1, 3'UTR 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 16/158 reads (10%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- AC005324.2 | c.982T>C p.Y328H | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100372141; called by muse, mutect2, varscan2
- ACVR1B | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99232227; called by muse, mutect2
- ADGRV1 | c.16775C>G p.P5592R | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67996239; called by muse, mutect2
- APOL5 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as COSV99968493; called by muse, mutect2, varscan2
- ARSD | c.1748G>A p.C583Y | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV66974051; called by muse, mutect2, varscan2
- CEMIP | c.3733G>A p.G1245S | Missense Mutation (SNP) | VAF 102/848 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1419264761, COSV55000937; called by muse, mutect2, varscan2
- CXCR3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as rs913064075, COSV65462239; called by muse, mutect2, varscan2
- DCT | c.555dup p.V186Cfs*9 | Frame Shift Ins (INS) | VAF 34/199 reads (17%) | catalogued as rs762895555; called by mutect2, varscan2
- DNAH1 | c.10942C>G p.L3648V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV70236990; called by muse, mutect2, varscan2
- DUSP10 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV60459908; called by muse, mutect2
- G3BP1 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62367024; called by muse, mutect2, varscan2
- GMIP | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV52291727; called by muse, mutect2, varscan2
- GPR4 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.965); catalogued as rs1409302412, COSV59918452; called by muse, mutect2, varscan2
- INAVA | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs776043601, COSV66256927, COSV66257679; called by muse, mutect2, varscan2
- LARP4B | c.759A>C p.E253D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60221729, COSV60223772, COSV60224227; called by muse, mutect2
- MINAR1 | c.1286C>A p.A429E | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as rs371873445, COSV100548845, COSV59587011; called by muse, mutect2, varscan2
- OR6F1 | c.833A>T p.N278I | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57469571; called by muse, mutect2, varscan2
- PITX1 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs140746945; called by muse, mutect2
- PTPRB | c.4753A>G p.T1585A | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54254874; called by muse, mutect2, varscan2
- SHMT1 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57398959, COSV57400774; called by muse, mutect2, varscan2
- STAT5A | c.98A>T p.Y33F | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.854); catalogued as COSV100604880, COSV61808648; called by muse, mutect2, varscan2
- TECTA | c.1237T>G p.L413V | Missense Mutation (SNP) | VAF 47/427 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs1301822819, COSV50814987; called by muse, mutect2, varscan2
- TEK | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV66235227; called by muse, mutect2
- TMEM131L | c.4409C>T p.P1470L | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV53645017; called by muse, mutect2, varscan2
- WRN | c.2525C>T p.P842L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53308024; called by muse, mutect2, varscan2
- ZNF133 | c.428C>T p.A143V (on ENST00000316358 / NM_001352454.2; = p.A142V on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/327 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100315704; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4594_4595del p.R1532Gfs*14 | Frame Shift Del (DEL) | VAF 20/182 reads (11%) | called by mutect2, pindel, varscan2
- ABCF3 | c.1530C>T p.R510= | Silent (SNP) | VAF 47/347 reads (14%) | catalogued as rs1212025963, COSV53054870; called by muse, mutect2, varscan2
- ADGRE2 | c.1263G>T p.L421= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV59696624; called by muse, mutect2, varscan2
- AHNAK | c.12495C>T p.I4165= | Silent (SNP) | VAF 42/348 reads (12%) | catalogued as COSV57232441; called by muse, mutect2, varscan2
- ASL | c.165C>T p.L55= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs776039671, COSV59188445; called by muse, mutect2, varscan2
- ATP1A3 | c.2838G>A p.S946= (on ENST00000545399 / NM_001256214.2; = p.S933= on NM_152296.5) | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as rs150417636; called by muse, mutect2, varscan2
- CDKN2D | c.462C>T p.L154= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV100224905; called by muse, mutect2, varscan2
- CEP290 | c.3321C>A p.I1107= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV58350135; called by muse, mutect2, varscan2
- EQTN | c.444C>T p.V148= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs765688896, COSV66218456; called by mutect2, varscan2
- KDM6A | c.3120C>T p.A1040= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV65046740; called by muse, mutect2, varscan2
- NLGN1 | c.1242T>C p.A414= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs1332307554, COSV64348110; called by muse, mutect2
- PCDHA2 | c.160C>T p.L54= | Silent (SNP) | VAF 14/232 reads (6%) | catalogued as COSV65371517; called by muse, mutect2
- PLEKHF1 | c.45C>T p.I15= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs1273866008, COSV101460807; called by muse, mutect2, varscan2
- PPIB | c.66C>G p.V22= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV55521405; called by mutect2, varscan2
- SLC5A2 | c.819T>C p.D273= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV57892599; called by muse, mutect2, varscan2
- SLC6A9 | c.690C>T p.A230= (on ENST00000360584 / NM_201649.4; = p.A176= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/232 reads (11%) | catalogued as rs200658319; called by muse, mutect2, varscan2
- ZNF408 | c.1554C>T p.H518= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as COSV61239440; called by muse, mutect2
- CCDC80 | c.*2C>T | 3'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99245458; called by muse, mutect2, varscan2
- CCNQP1 | n.90G>T | RNA (SNP) | VAF 12/388 reads (3%) | called by muse, mutect2
